Somatic mutation profile of tumor specimen C3N-01344-01 (aliquot CPT0116340007) from CPTAC case C3N-01344, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.1 years (29,270 days).
Specimen C3N-01344-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7de8e063-7fbd-4020-b350-a4d801363805.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01344-31 (Blood Derived Normal), aliquot CPT0116540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/265aedde-6c8c-422a-b6d8-7e8afa1ee89c

The open-access MAF lists 118 somatic variants for this specimen: 82 protein-altering or splice-affecting, 25 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 25, Nonsense Mutation 4, 5'Flank 4, Splice Site 3, 5'UTR 2, 3'UTR 2, Frame Shift Del 2, Intron 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 108/381 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 228/481 reads (47%) | catalogued as rs786204910, CM110130, CM1513152, COSV64288346; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.79T>A p.Y27N | Missense Mutation (SNP) | VAF 76/404 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs746128825, CM147224, COSV64290549, COSV64290556, COSV64292877; called by muse, varscan2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 72/792 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2
- ACTB | c.364-1G>A p.X122_splice | Splice Site (SNP) | VAF 18/412 reads (4%) | catalogued as COSV59316501; called by muse, mutect2
- ADARB2 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs144565549; called by muse, mutect2
- ANKRD26 | c.2930G>A p.R977Q | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763003415, COSV65774563; called by muse, mutect2, varscan2
- ARID1A | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 93/150 reads (62%) | catalogued as COSV61377198, COSV61384452, COSV61387404; called by muse, mutect2, varscan2
- C10orf88 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777512199; called by muse, mutect2, varscan2
- C11orf95 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); catalogued as rs1301521859; called by muse, mutect2
- CACNA1A | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1472719188; called by muse, mutect2
- CAMP | c.316G>A p.G106R (on ENST00000296435; = p.G103R on NM_004345.5) | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs758490185, COSV56481725; called by muse, mutect2, varscan2
- CASP14 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs562909688; called by muse, mutect2, varscan2
- CCDC136 | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774739139, COSV52796030; called by muse, mutect2, varscan2
- CHD4 | c.3274C>T p.R1092W (on ENST00000357008 / NM_001363606.2; = p.R1105W on NM_001273.5) | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58898720; called by muse, mutect2, varscan2
- CLEC14A | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV60561804; called by muse, mutect2, varscan2
- EVI5L | c.2224G>A p.V742I | Missense Mutation (SNP) | VAF 161/537 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as rs1428106195, COSV54483634; called by muse, mutect2, varscan2
- FAM163B | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs760339559; called by muse, mutect2, varscan2
- FLT3 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99610429; called by muse, mutect2, varscan2
- GAB2 | c.1990G>A p.V664M (on ENST00000361507 / NM_080491.3; = p.V626M on NM_012296.3) | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as rs781659629, COSV60866527; called by muse, mutect2
- HDC | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs778709808, COSV51071127; called by muse, mutect2, varscan2
- HDLBP | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 21/422 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV60501300; called by muse, mutect2
- HKDC1 | c.1631A>G p.K544R | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.018); catalogued as rs141879185, COSV63577628; called by muse, mutect2, varscan2
- IL17A | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs760902102, COSV60684014; called by muse, mutect2
- ITGAM | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 80/335 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.848); catalogued as rs541727151; called by muse, mutect2, varscan2
- KCNA6 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 24/447 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.514); catalogued as rs1285186513; called by muse, mutect2
- KIAA1549 | c.2733G>T p.E911D | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.107); catalogued as COSV104386723; called by muse, mutect2, varscan2
- KLRC2 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67900303; called by muse, mutect2
- KRT83 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 136/735 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.171); catalogued as rs774021555; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2696C>T p.T899M | Missense Mutation (SNP) | VAF 106/329 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs769907593; called by muse, mutect2, varscan2
- MLF1 | c.47+1G>A p.X16_splice | Splice Site (SNP) | VAF 48/175 reads (27%) | catalogued as COSV63033736; called by muse, mutect2, varscan2
- MTCL1 | c.3449G>A p.R1150H (on ENST00000306329 / NM_001378206.1; = p.R831H on NM_015210.4) | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs199934266; called by muse, mutect2, varscan2
- MUC4 | c.15115G>A p.E5039K (on ENST00000463781 / NM_018406.7; = p.E803K on NM_004532.6) | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV100204961, COSV57790506; called by muse, mutect2, varscan2
- MXRA5 | c.6076G>A p.V2026M | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs375991615, COSV54237684; called by muse, mutect2, varscan2
- MYO1D | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 18/345 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs765554830, COSV59009345; called by muse, mutect2
- NDST1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 45/719 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765517040; called by muse, mutect2
- ODF2 | c.2344C>T p.R782C (on ENST00000434106 / NM_153433.2; = p.R758C on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs146801126, COSV59407339; called by muse, mutect2, varscan2
- PCDHA13 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 80/312 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs782410675; called by muse, mutect2, varscan2
- PEAK1 | c.5038G>A p.A1680T | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs201627499; called by muse, mutect2, varscan2
- PFN2 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs752216082, COSV53524072; called by muse, mutect2, varscan2
- PITPNM3 | c.2345C>T p.T782M | Missense Mutation (SNP) | VAF 35/467 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs773688730; called by muse, mutect2
- PLIN5 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 82/294 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs553049950; called by muse, mutect2, varscan2
- PLXNB1 | c.891C>G p.F297L | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV56488306; called by muse, mutect2, varscan2
- PTPRF | c.4027C>T p.R1343C | Missense Mutation (SNP) | VAF 45/358 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs369549174; called by muse, mutect2, varscan2
- RALY | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 118/487 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1253878098; called by muse, mutect2, varscan2
- SHROOM2 | c.3238G>A p.G1080S | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV66610310; called by muse, mutect2
- SIPA1L3 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV99728449; called by muse, mutect2, varscan2
- SNX20 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs772016083, COSV100319197; called by muse, mutect2
- SPANXB1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 182/1605 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs1302097442, COSV71886004; called by muse, mutect2, varscan2
- SSC5D | c.3836C>T p.T1279M | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.158); catalogued as rs202079962, COSV67476498; called by muse, mutect2
- TNN | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 29/427 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs150010255, COSV53431546; called by muse, mutect2
- TRAV1-1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 75/389 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs200370511; called by muse, mutect2, varscan2
- ZNF174 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.426); catalogued as rs1039890841; called by muse, mutect2
- ZNF260 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763990138; called by muse, mutect2, varscan2
- ZNF835 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 138/409 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV101606357; called by muse, mutect2, varscan2
- ANHX | c.776A>G p.E259G | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASH1L | c.6445C>T p.R2149* (on ENST00000368346 / NM_001366177.2; = p.R2144* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 82/906 reads (9%) | called by muse, mutect2
- BAZ2B | c.4498dup p.Y1500Lfs*27 | Frame Shift Ins (INS) | VAF 57/281 reads (20%) | called by mutect2, pindel, varscan2
- CHD4 | c.1089C>G p.C363W (on ENST00000357008 / NM_001363606.2; = p.C376W on NM_001273.5) | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FNDC3B | c.3388C>A p.R1130S | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- FOXI2 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- GPR143 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.828); called by muse, mutect2
- ITGB1 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 36/293 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- JAG1 | c.501G>T p.W167C | Missense Mutation (SNP) | VAF 92/340 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCTD19 | c.1043A>G p.E348G | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KPNA7 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAP11 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MGST3 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 117/814 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTSS2 | c.206-8_206-1del p.X69_splice | Splice Site (DEL) | VAF 34/203 reads (17%) | called by mutect2, pindel, varscan2
- NDUFA12 | c.263del p.R88Lfs*6 | Frame Shift Del (DEL) | VAF 52/351 reads (15%) | called by mutect2, pindel, varscan2
- PAGE1 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RC3H1 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 40/846 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2
- RYR1 | c.5216C>A p.P1739H | Missense Mutation (SNP) | VAF 293/900 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SPATA31A1 | c.3449T>C p.L1150P | Missense Mutation (SNP) | VAF 58/812 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2
- SPTAN1 | c.3569C>G p.S1190C | Missense Mutation (SNP) | VAF 104/381 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TAF1 | c.5266G>T p.E1756* (on ENST00000373790 / NM_138923.4; = p.E1777* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 79/258 reads (31%) | called by muse, mutect2, varscan2
- TAF4 | c.2784del p.Y928* | Frame Shift Del (DEL) | VAF 102/378 reads (27%) | called by mutect2, pindel, varscan2
- TULP4 | c.3509C>T p.S1170F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- UVSSA | c.521G>C p.R174T | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2
- ZNF175 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZNF652 | c.1401G>T p.K467N | Missense Mutation (SNP) | VAF 99/289 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AC092143.1 | c.2331C>T p.A777= | Silent (SNP) | VAF 64/367 reads (17%) | catalogued as rs200607346, COSV100205674; called by muse, mutect2, varscan2
- ADRA2A | c.1029G>A p.P343= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2
- APCDD1 | c.447C>T p.N149= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as rs780268952; called by muse, mutect2, varscan2
- ATG16L2 | c.300C>T p.L100= | Silent (SNP) | VAF 44/148 reads (30%) | called by muse, mutect2
- BCL11B | c.1467C>T p.D489= (on ENST00000357195 / NM_001282237.2; = p.D418= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 123/441 reads (28%) | catalogued as rs1252307867; called by muse, mutect2, varscan2
- BTBD17 | c.339C>T p.A113= | Silent (SNP) | VAF 18/182 reads (10%) | catalogued as rs200070807, COSV64729408; called by muse, mutect2
- C20orf203 | c.519G>A p.K173= | Silent (SNP) | VAF 108/338 reads (32%) | called by muse, mutect2, varscan2
- CDC42EP1 | c.213C>T p.S71= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as rs776700659, COSV50758770; called by muse, mutect2, varscan2
- CUX2 | c.2736C>T p.N912= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV55632167; called by muse, mutect2, varscan2
- ILRUN | c.126C>G p.A42= | Silent (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- KITLG | c.744T>A p.V248= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- KRT38 | c.714C>T p.L238= | Silent (SNP) | VAF 20/191 reads (10%) | called by muse, mutect2
- NCKAP5L | c.1932G>A p.K644= | Silent (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- NFATC2 | c.258C>T p.F86= | Silent (SNP) | VAF 64/192 reads (33%) | catalogued as rs1348596949, COSV65354335; called by muse, mutect2, varscan2
- OR10Q1 | c.763C>T p.L255= | Silent (SNP) | VAF 54/186 reads (29%) | called by muse, mutect2, varscan2
- OTUD7A | c.1752G>A p.A584= (on ENST00000307050 / NM_001382637.1; = p.A577= on NM_130901.3) | Silent (SNP) | VAF 62/338 reads (18%) | called by muse, mutect2, varscan2
- RPAP2 | c.132A>G p.L44= | Silent (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- SLC45A4 | c.1269C>T p.A423= (on ENST00000517878 / NM_001286646.2; = p.A372= on NM_001080431.2) | Silent (SNP) | VAF 20/301 reads (7%) | called by muse, mutect2
- STT3B | c.261G>C p.S87= | Silent (SNP) | VAF 85/309 reads (28%) | called by muse, mutect2, varscan2
- TMEM151A | c.1245G>A p.T415= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs770742647; called by muse, mutect2
- TPO | c.1017G>A p.Q339= | Silent (SNP) | VAF 200/596 reads (34%) | called by muse, mutect2, varscan2
- TSHZ3 | c.2661C>T p.P887= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs148165190; called by muse, mutect2, varscan2
- UBE2O | c.1053G>A p.E351= | Silent (SNP) | VAF 30/266 reads (11%) | called by muse, mutect2, varscan2
- USP6 | c.4197C>T p.Y1399= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as rs1324954777; called by muse, mutect2, varscan2
- WNK2 | c.1134C>T p.D378= | Silent (SNP) | VAF 71/224 reads (32%) | catalogued as rs774737755, COSV52941509; called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57610267 G>A | 5'Flank (SNP) | VAF 14/47 reads (30%) | catalogued as COSV99677810; called by muse, mutect2, varscan2
- BCORL1 | c.4306-2704G>A | Intron (SNP) | VAF 77/340 reads (23%) | catalogued as rs762735567, COSV99501140; called by muse, mutect2, varscan2
- C5orf38 | c.*267C>T | 3'UTR (SNP) | VAF 142/433 reads (33%) | catalogued as rs1488752769; called by muse, mutect2, varscan2
- KATNB1 | c.-217T>C | 5'UTR (SNP) | VAF 88/281 reads (31%) | called by muse, mutect2, varscan2
- MECOM | c.-72del | 5'UTR (DEL) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- PIK3R3 | chr1:46132700 C>T | 5'Flank (SNP) | VAF 14/120 reads (12%) | called by mutect2, varscan2
- RAB18 | c.*2433T>A | 3'UTR (SNP) | VAF 32/184 reads (17%) | called by muse, mutect2, varscan2
- SLC7A9 | c.749+33C>T | Intron (SNP) | VAF 59/339 reads (17%) | catalogued as rs370792507; called by muse, mutect2, varscan2
- USP27X | chrX:49878690 G>T | 5'Flank (SNP) | VAF 58/606 reads (10%) | called by muse, mutect2
- WASF4P | n.333del | RNA (DEL) | VAF 113/578 reads (20%) | called by mutect2, pindel, varscan2
- ZNF33A | chr10:38010663 G>A | 5'Flank (SNP) | VAF 30/250 reads (12%) | catalogued as rs748208671; called by muse, mutect2, varscan2
